Somatic mutation profile of tumor specimen TCGA-AX-A05W-01A (aliquot TCGA-AX-A05W-01A-21W-A027-09) from TCGA case TCGA-AX-A05W, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 60.8 years (22,200 days).
Specimen TCGA-AX-A05W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5280d34a-135d-45ca-9584-033b1dc93c8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A05W-10A (Blood Derived Normal), aliquot TCGA-AX-A05W-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d84de807-afeb-4fdd-85ab-c892404ba2ed

The open-access MAF lists 81 somatic variants for this specimen: 60 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 19, Nonsense Mutation 7, Frame Shift Ins 3, Frame Shift Del 3, 5'Flank 1, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 79/403 reads (20%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 16/82 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- HPSE2 | c.57dup p.A20Rfs*45 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | catalogued as rs778121647; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 65/120 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 13/106 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1325_1327del p.I442_E443delinsK (on ENST00000521381 / NM_181523.3; = p.I172_E173delinsK on NM_181504.4) | In Frame Del (DEL) | VAF 15/42 reads (36%) | hotspot (GDC flag); catalogued as COSV57141036; called by mutect2, pindel, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 182/410 reads (44%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 103/405 reads (25%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCD3 | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64644767; called by muse, mutect2
- ATF7IP | c.2098G>T p.E700* | Nonsense Mutation (SNP) | VAF 40/119 reads (34%) | catalogued as COSV53775791; called by muse, mutect2, varscan2
- ATIC | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 75/498 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); catalogued as COSV52695605; called by muse, mutect2, varscan2
- BAZ1B | c.3722G>A p.R1241H | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782273444, COSV59994954; called by muse, mutect2, varscan2
- CCKAR | c.754+1G>A p.X252_splice | Splice Site (SNP) | VAF 89/326 reads (27%) | catalogued as COSV55164324; called by muse, mutect2, varscan2
- CFAP69 | c.2267T>G p.I756S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV60188824; called by muse, mutect2, varscan2
- CFH | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1300493671, COSV62776836; called by muse, mutect2, varscan2
- CPXM2 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 38/870 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99583486; called by muse, mutect2
- CYLC1 | c.1286C>G p.S429* | Nonsense Mutation (SNP) | VAF 12/276 reads (4%) | catalogued as COSV100255584; called by muse, mutect2
- CYP2A13 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs187221928, COSV57836160, COSV57840387; called by mutect2, varscan2
- CYP4F12 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as rs763663657, COSV61176998; called by muse, mutect2, varscan2
- DICER1 | c.1994C>T p.S665L | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.99); catalogued as COSV58629159; called by muse, mutect2
- DNAAF4 | c.755G>C p.R252P | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs889125391, COSV100336966, COSV58251964; called by muse, mutect2
- ERMARD | c.287C>G p.P96R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.533); catalogued as COSV64651714; called by muse, mutect2, varscan2
- FHOD3 | c.3137G>A p.R1046Q (on ENST00000359247 / NM_001281739.3; = p.R1063Q on NM_025135.5) | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1192799141, COSV57190056; called by muse, mutect2, varscan2
- HNRNPU | c.842G>T p.G281V (on ENST00000283179; = p.G343V on NM_004501.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51694641; called by muse, mutect2, varscan2
- HOMER1 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV56531040; called by muse, mutect2, varscan2
- KCNN2 | c.1693C>T p.R565W (on ENST00000264773; = p.R777W on NM_021614.4) | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as rs79675198, COSV53283201; called by muse, mutect2, varscan2
- KIRREL2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761189830, COSV52877346; called by muse, mutect2, varscan2
- MAN1A2 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV100741086; called by muse, mutect2
- MTMR8 | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as COSV66396543; called by muse, mutect2, varscan2
- NAV2 | c.4340C>T p.P1447L (on ENST00000396087 / NM_001244963.2; = p.P1424L on NM_145117.5) | Missense Mutation (SNP) | VAF 14/323 reads (4%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100217731; called by muse, mutect2
- NCL | c.1259G>T p.R420I | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100502493; called by muse, mutect2
- NLRC5 | c.5212G>A p.E1738K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV52664162; called by muse, mutect2
- NRG3 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64547677, COSV64586620; called by muse, mutect2
- NUMA1 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV61191682; called by muse, mutect2, varscan2
- PCDHB13 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.962); catalogued as rs782262286, COSV53398900; called by muse, mutect2, varscan2
- PCDHB6 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV50694787; called by muse, varscan2
- PLXNA4 | c.2064C>A p.C688* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV58163763; called by muse, mutect2
- PRKCB | c.1011G>A p.M337I | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV57804031; called by muse, mutect2
- PRPF4B | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV61786168; called by muse, mutect2, varscan2
- PTPRZ1 | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 223/432 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101100164, COSV66446495; called by muse, mutect2, varscan2
- RAB3GAP1 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51489603; called by muse, mutect2, varscan2
- RNF19A | c.1367G>T p.R456L | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100348192, COSV61994184; called by muse, mutect2
- SARDH | c.511C>A p.L171M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV53836152; called by muse, mutect2, varscan2
- SERPINA6 | c.440T>A p.I147N | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV58587921; called by muse, mutect2, varscan2
- SYTL4 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs148610544, COSV52166691; called by muse, mutect2
- TDRD6 | c.2699T>G p.V900G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60179154; called by muse, mutect2
- TKTL1 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs781944208, COSV54215285; called by muse, mutect2, varscan2
- TRIM32 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100523829, COSV57821165; called by muse, mutect2, varscan2
- USH2A | c.9935G>A p.G3312E | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV56446665; called by muse, mutect2, varscan2
- USP22 | c.1573del p.E525Sfs*74 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | catalogued as COSV54947074, COSV54949296; called by mutect2, pindel, varscan2
- WLS | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 55/152 reads (36%) | catalogued as rs375331655; called by muse, mutect2, varscan2
- ZBTB16 | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as rs1565602954, COSV60100251; called by muse, mutect2, varscan2
- ACACA | c.6128C>T p.S2043F | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARID1A | c.6706dup p.R2236Pfs*42 | Frame Shift Ins (INS) | VAF 30/83 reads (36%) | called by mutect2, pindel, varscan2
- CSMD3 | c.5158G>T p.G1720W (on ENST00000297405 / NM_001363185.1; = p.G1616W on NM_052900.3) | Missense Mutation (SNP) | VAF 7/203 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GALNT10 | c.825_829del p.Y276Dfs*12 | Frame Shift Del (DEL) | VAF 21/147 reads (14%) | called by mutect2, pindel, varscan2
- HSP90B1 | c.1224_1228del p.Y408* | Frame Shift Del (DEL) | VAF 29/120 reads (24%) | called by mutect2, pindel, varscan2
- IGHM | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SPATS2L | c.536_539dup p.A181Vfs*3 | Frame Shift Ins (INS) | VAF 40/225 reads (18%) | called by mutect2, pindel, varscan2
- ACSF2 | c.651C>T p.I217= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV51974445; called by muse, mutect2, varscan2
- CEMIP2 | c.600G>A p.A200= | Silent (SNP) | VAF 80/200 reads (40%) | catalogued as COSV65486805; called by muse, mutect2, varscan2
- CENPJ | c.2658A>G p.E886= | Silent (SNP) | VAF 56/240 reads (23%) | catalogued as COSV67884378; called by muse, mutect2, varscan2
- DCTN4 | c.738G>A p.Q246= | Silent (SNP) | VAF 47/221 reads (21%) | catalogued as COSV69783160; called by muse, mutect2, varscan2
- DDR1 | c.2469G>T p.A823= (on ENST00000324771; = p.A786= on NM_001954.4) | Silent (SNP) | VAF 4/86 reads (5%) | catalogued as rs993900172, COSV100242220; called by muse, mutect2
- GBF1 | c.4341G>A p.G1447= (on ENST00000369983 / NM_001377137.1; = p.G1446= on NM_004193.3) | Silent (SNP) | VAF 30/171 reads (18%) | catalogued as COSV64149514; called by muse, mutect2, varscan2
- IGF2R | c.1521G>T p.T507= | Silent (SNP) | VAF 9/246 reads (4%) | catalogued as COSV100808310, COSV100808347; called by muse, mutect2
- IGHV3OR16-8 | c.276C>T p.D92= | Silent (SNP) | VAF 22/588 reads (4%) | called by muse, mutect2
- KCNC2 | c.1051A>C p.R351= | Silent (SNP) | VAF 40/197 reads (20%) | catalogued as rs1399883583, COSV54381275; called by muse, mutect2, varscan2
- KHDRBS1 | c.1050G>A p.A350= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs373128165, COSV56980685; called by muse, mutect2, varscan2
- NOS1 | c.4260C>T p.F1420= | Silent (SNP) | VAF 28/425 reads (7%) | catalogued as COSV57622909; called by muse, mutect2
- NUFIP2 | c.1161C>T p.T387= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as rs752836574, COSV56602472, COSV99837452; called by muse, mutect2, varscan2
- OR6C75 | c.459C>A p.I153= | Silent (SNP) | VAF 48/224 reads (21%) | catalogued as COSV58553024, COSV58553674; called by muse, mutect2, varscan2
- RASIP1 | c.1860T>C p.R620= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV55808725; called by muse, mutect2, varscan2
- SCN3A | c.1884C>A p.A628= | Silent (SNP) | VAF 70/149 reads (47%) | catalogued as COSV51819384, COSV51826084; called by muse, mutect2, varscan2
- SERPINI1 | c.799C>T p.L267= | Silent (SNP) | VAF 69/160 reads (43%) | catalogued as COSV55515376, COSV99855398; called by muse, mutect2, varscan2
- SYNRG | c.2046A>C p.L682= | Silent (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- SYT16 | c.783C>T p.Y261= | Silent (SNP) | VAF 55/136 reads (40%) | catalogued as rs377092097; called by muse, mutect2, varscan2
- VRK1 | c.639C>T p.Y213= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as rs1217274457, COSV53711822; called by muse, mutect2, varscan2
- OR5H1 | chr3:98132696 A>G | 5'Flank (SNP) | VAF 119/397 reads (30%) | catalogued as COSV100641790; called by muse, mutect2, varscan2
- SKP2 | c.1062-1584_1062-1582del | Intron (DEL) | VAF 105/340 reads (31%) | catalogued as rs1470941994; called by mutect2, pindel, varscan2
